Somatic mutation profile of tumor specimen 0DSJYA from CCDI case PBCICZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DSJYA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3db1e291-a36a-4171-a821-44cf5223f491.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSJYK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20fb01f2-2b3a-45c2-9a52-5d8eee286c3f

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCG2 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 269/566 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs372239904; called by muse, mutect2, varscan2
- CHD4 | c.5258C>G p.P1753R (on ENST00000357008 / NM_001363606.2; = p.P1764R on NM_001273.5) | Missense Mutation (SNP) | VAF 24/877 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 66/1420 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- MACF1 | c.1369-58G>A | Intron (SNP) | VAF 169/376 reads (45%) | called by muse, mutect2, varscan2
